TCGA case TCGA-V4-A9EF — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a18d3ba3-e2f4-4144-9c25-2019cad193f4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 56 years; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Spindle cell melanoma, NOS: ICD-O-3 morphology code: 8772/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Classification of tumor: primary; Age at diagnosis: 56.8 years (20,763 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,895 days (7.9 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Consistent pathology review: Yes; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: >90%; Tumor depth measurement: 14; Tumor shape: Mushroom.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 16.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 42 days; Days to treatment end: 223 days; Number of cycles: 5; Treatment dose: 75 mg/m2; Reason treatment ended: Course of Therapy Completed.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 719 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 824 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,165 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 2,895 days (7.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 16.

Other clinical attributes
- Eye color: Brown.
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 170 cm; BMI: 28.4.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample TCGA-V4-A9EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
- Sample TCGA-V4-A9EF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,165 days; disease-specific survival: no event (censored), 1,165 days; progression-free interval: no event (censored), 1,165 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EF-01A-21D-A39V-01): tumor purity 0.97, ploidy 2, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- days to followup: 2895
- days to imaging: 2841
- days to outcome: 2895
- days to pharm therapy imaging 1: 251
- days to procedure 1: 0
- diagnosis: melanoma
- disease status at last followup: No Evidence of Disease
- drug name 1: fotemustin
- evaluated by imaging: yes
- imaging type: liver MRI
- line of therapy 1: first
- m stage: M0
- morphologic subtype: spindle
- n stage: N0
- number cycles 1: 5
- outcome: Complete Response
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy evaluated by imaging 1: yes
- pharm therapy imaging type 1: MRI
- pharm therapy status 1: completed as planned
- resection status 1: R0
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4b
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
